Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAES, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAES-01A (Primary Tumor).

ICD-O-3
Seminoma NOS 9061/3
Site (R) Testis NOS
C62.9
JW 2/3/14

Direct dial
Mobile
Internal postal address
E-mail
Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 5,3 cm; no angio-invasion; no invasion of tunica albuginea.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

iHPAA Discrepancy		

Source: NCI Genomic Data Commons file fb2358e1-4923-486a-956e-0f7e018a25b4 (TCGA-2G-AAES-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).